Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A4FQ, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A4FQ-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Gender:

HCN:

Ordering MD:

Copy To:

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

100-0-3

Specimen(s) Received

1. Soft-Tissue: Right Posterior Triangle, stitch marks apex
2. Lymph node: Right jugular nodes stitch marks Apex
3. Lymph node: Right para tracheal nodes (Fresh for tumour bank)
4. Parathyroid: Left lower parathyroid QS
5. Lymph node: Left paratracheal nodes (fresh for tumour bank)
6. Thyroid: Total thyroid, stitch marks upper pole right lobe (fresh for tumour bank)
7. Parathyroid: Left lower parathyroid

Path: carcinoma, papillary and follicular 8340/3
CQLE: Carcinoma, papillary, follicular variant 8340/3
Site: thyroid, NOS C73.9
lw
10/2/12

Diagnosis

1. Metastatic papillary thyroid carcinoma: Lymph nodes, 2 of 5 (right neck posterior triangle) dissection specimen
2. Metastatic papillary thyroid carcinoma: Lymph nodes, 9 of 34 (right neck jugular) dissection specimen
3. Metastatic papillary thyroid carcinoma: Lymph nodes, 2 of 3 (right paratracheal) dissection specimen
4. No pathological diagnosis: Soft tissue (labelled as "left lower parathyroid") excisional biopsy
5. Metastatic papillary thyroid carcinoma: Lymph nodes, 2 of 7 (left paratracheal) dissection specimen
6. Bilateral multifocal papillary carcinoma, dominant follicular variant with oncocytic change, 3.5 cm, right; underlying chronic lymphocytic thyroiditis: Thyroid
Cellular gland: Parathyroid, right perithyroidal
Metastatic papillary thyroid carcinoma: Lymph nodes, 2 of 6, central neck
- Total thyroidectomy specimen with central neck dissection
7. No pathological diagnosis: Parathyroid (left lower) excisional biopsy

Comment

The thyroidectomy specimen contains bilateral multifocal papillary carcinoma. The dominant 3.5 cm is a follicular variant papillary carcinoma that exhibits oncocytic change. The second dominant is a 2.1 cm widely invasive classical variant papillary carcinoma that exhibits focal tall cell change (<10%) and Warthin-like change. Additional multiple papillary microcarcinomas ranging from 0.1 cm to 0.7 cm are also seen in the left lobe.

Synoptic Data

Procedure:

Received:

Specimen Integrity:

Other: Total thyroidectomy with central and right neck dissection

Fresh

Intact

[page 2 of 4]
Surgical Pathology Consultation Report

Specimen Size: Right lobe:
5.5 cm
3.5 cm
3.0 cm
Left lobe:
3.3 cm
1.5 cm
1.2 cm
Isthmus +/- pyramidal lobe:
4.0 cm
1.5 cm
0.3 cm
Specimen Weight: 37.8 g
Tumor Focality: Multifocal

----- DOMINANT TUMOR -----

Tumor Laterality: Right lobe
Tumor Size: Greatest dimension: 3.5cm
Additional dimension: 3.0 cm
Additional dimension: 3.0 cm
Histologic Type: Papillary carcinoma, follicular variant *per TSS, follicular variant = 100%*
Papillary carcinoma, other variant: with oncocyctic change
Follicular architecture
Classical cytomorphology
Oncocytic or oxyphilic cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Tumor Capsule: Partially encapsulated
Tumor Capsular Invasion: Not identified
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified

----- SECOND TUMOR -----

Tumor Laterality: Right lobe
Tumor Size: Greatest dimension: 2.1cm
Additional dimension: 1.7 cm
Additional dimension: 1.6 cm
Histologic Type: Papillary carcinoma, classical (usual)
Papillary carcinoma, other: with focal tall cell change (<10%) and Warthin-like change
Classical (papillary) architecture
Classical cytomorphology
Oncocytic or oxyphilic cytomorphology
Tall cell cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Tumor Capsule: Partially encapsulated
Tumor Capsular Invasion: Present, extent widely invasive
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
TNM Descriptors: m (multiple primary tumors)
Primary Tumor (pT): pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid
Regional Lymph Nodes (pN): pN1b: Metastases to unilateral, bilateral or contralateral cervical or superior mediastinal lymph nodes
Number of regional lymph nodes examined: 55
Number of regional lymph nodes involved: 17
Lymph Node, Extranodal Extension Not identified
Distant Metastasis (pM): Not applicable
Additional Pathologic Findings: Thyroiditis
Parathyroid gland(s), within normal limits

[page 3 of 4]
Surgical Pathology Consultation Report

Parathyroid gland(s), hypercellular

Other: additional multiple smaller papillary microcarcinomas ranging from 0.1 cm to 0.7 cm in the left lobe

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:

Clinical History

Papillary thyroid carcinoma

Gross Description

1. The specimen labeled with the patient's name and as "Right posterior triangle stitch marks apex", and consists of a piece of fibrofatty tissue and muscle measuring 8.5 cm x 1.7 x 1.0 cm. Within the tissue are multiple lymph nodes that range in maximum dimension from 0.1 to 1.7 cm. Representative sections, lymph nodes submitted in as they occur from apex to base.

- 1A multiple lymph nodes
- 1B 1 lymph node, bisected
- 1C multiple lymph nodes

2. The specimen labeled with the patient's name and as "Right jugular nodes stitch marks apex", and consists of a piece of fibrofatty tissue measuring 9.5 x 3.0 x 0.7 cm. Within the tissue are multiple lymph nodes that range in maximum dimension from 0.1 to 1.7 cm. Representative sections, lymph nodes submitted in as they occur from apex to base.

2A-E multiple lymph nodes, per block

3. The specimen labeled with the patient's name and as "Right paratracheal nodes", consists of a piece of fibrofatty tissue measuring 3.5 x 2.1 x 1.2 cm the specimen is painted with silver nitrate. Within the tissue are 3 lymph nodes that range from 0.5 to 1.4 cm. Tissue from the largest lymph node is stored frozen. Representative sections, lymph nodes submitted in

- 3A 2 lymph nodes
- 3B remainder of lymph node from which tissue has been frozen

4. The specimen labeled with the patient's name and as "Left lower parathyroid QS", consists of a tiny piece of tissue that measures 0.3 x 0.2 x 0.1 cm and weighs 0.010 g. The specimen is submitted in for intraoperative consultation.

4A frozen tissue resubmitted

5. The specimen labeled with the patient's name and as "Left paratracheal", consists of a piece of fibrofatty tissue that measures 2.3 x 1.5 x 1.0 cm. Within the tissue are multiple lymph nodes that range from 0.2 to 1.5 cm in maximum dimension representative sections, lymph nodes submitted in

- 5A multiple lymph nodes
- 5B 1 lymph node, bisected

6. The specimen labeled with the patient's name and as "Total thyroid, stitch marks upper pole right lobe (fresh for tumor bank)" consists of an oriented thyroid gland that weighs 37.8 g. The right lobe measures 5.5 cm SI x 3.5 cm ML x 3.0 cm AP, the left lobe measures 3.3 cm SI x 1.5 cm ML x 1.2 cm AP and the isthmus measures 4.0 cm SI x 1.5 cm ML x 0.3 cm AP. The external surfaces have fibrous adhesions and are painted with blue ink. There is a small amount of fibrofatty tissue at the inferior edge of the isthmus. Within this are multiple lymph nodes that range from pinpoint to 0.5 cm. The right lobe contains 2 delineated nodules that measure 2.1 cm SI x 1.7 cm ML x 1.6 cm AP and 3.0 cm SI x 3.5 cm ML x 3.0 cm AP. The smaller nodule has a gritty white tan well-circumscribed appearance. The larger nodule is mostly cystic with a solid nodule measuring 1.5 cm in maximum diameter. The cyst contains bloody fluid. The left lobe contains 1 delineated nodule that measures 0.5 cm SI x 0.7 cm ML x 0.3 cm AP. The nodule has a white tan, well-circumscribed appearance. The remainder of the thyroid tissue is unremarkable. Sections of all the nodules and normal tissue are stored frozen. Representative sections of the remainder of the specimen are submitted as follows:

6A-G right lobe, superior to inferior (smaller nodule in A and B, larger nodule in C-G)

[page 4 of 4]
Dr. [REDACTED]

Surgical Pathology Consultation Report

6H isthmus
6I-N left lobe, superior to inferior (nodule in in K-N)
6O multiple lymph nodes

7. The specimen labeled with the patient's name and as "Left lower parathyroid", consists of a tiny piece of tissue measuring 0.4 x 0.3 x 0.1 cm. The specimen is submitted in for intraoperative consultation.
7A frozen tissue resubmitted

Quick Section Diagnosis

4. Left lower parathyroid: : Portion of fibrovascular tissue; no parathyroid identified.
Case reported to OR at

7. Left lower parathyroid; Parathyroid present.
Case reported to OR at : pagged with result.

Source: NCI Genomic Data Commons file 34a2a55a-ab3b-44de-85c6-4d04999641d6 (TCGA-EM-A4FQ.61E917B8-556F-4BA7-916D-1D8295FCB2EE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).